Somatic mutation profile of tumor specimen MP2PRT-PAVTDJ-TMP1-A (aliquot MP2PRT-PAVTDJ-TMP1-A-1-0-D-A82B-36) from MP2PRT case MP2PRT-PAVTDJ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.8 years (2,498 days).
Specimen MP2PRT-PAVTDJ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 107c4a07-6336-45a2-97bc-2b0fef52b1fa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVTDJ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVTDJ-NB1-A-1-0-D-A82B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2fb5352e-81b9-4ef8-bd45-bf012ce5506a

The open-access MAF lists 10 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 1, 5'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA1D | c.2464G>A p.D822N (on ENST00000350061 / NM_001128840.3; = p.D842N on NM_000720.4) | Missense Mutation (SNP) | VAF 46/365 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs745329034; called by muse, mutect2, varscan2
- DNAH9 | c.7150G>A p.G2384R | Missense Mutation (SNP) | VAF 30/370 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs267604735; called by muse, mutect2
- MTMR11 | c.1909C>T p.R637C (on ENST00000439741 / NM_001145862.2; = p.R565C on NM_181873.3) | Missense Mutation (SNP) | VAF 42/404 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs371578546; called by mutect2, varscan2
- NSD2 | c.3295G>A p.E1099K | Missense Mutation (SNP) | VAF 54/507 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs772470710, COSV56386422; ClinVar: uncertain significance; called by muse, varscan2
- EPS8L2 | c.996G>C p.Q332H | Missense Mutation (SNP) | VAF 55/458 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.459); called by mutect2, varscan2
- HTR1A | c.940A>G p.T314A | Missense Mutation (SNP) | VAF 63/557 reads (11%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2, varscan2
- PGBD1 | c.1983G>A p.M661I | Missense Mutation (SNP) | VAF 40/360 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.308); called by mutect2, varscan2
- PSTPIP1 | c.150_151dup p.E51Gfs*24 | Frame Shift Ins (INS) | VAF 42/477 reads (9%) | called by mutect2, pindel
- CA2 | c.711A>G p.E237= | Silent (SNP) | VAF 29/387 reads (7%) | called by muse, mutect2
- TRDJ1 | chr14:22449112 ins GGGT | 5'Flank (INS) | VAF 31/209 reads (15%) | called by mutect2, pindel, varscan2
